Somatic mutation profile of tumor specimen MBCProject_4647_T1_WES (aliquot MBCProject_4647_T1_WES_1) from CMI case MBCProject_4647, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 62.4 years (22,794 days).
Specimen MBCProject_4647_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4fd42ac-d65e-436b-8f1e-3679dfc09744.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4647_SALIVA (Saliva), aliquot MBCProject_4647_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fb66dfb-a60b-478e-b645-1ccde81d259c

The open-access MAF lists 91 somatic variants for this specimen: 58 protein-altering or splice-affecting, 21 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 21, Intron 6, 5'UTR 3, Nonsense Mutation 3, Splice Region 2, Frame Shift Del 2, RNA 1, 5'Flank 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL3 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53298819, COSV53300607; called by muse, mutect2, varscan2
- CACNA2D3 | c.2812C>T p.L938F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs941796977; called by muse, mutect2, varscan2
- CADPS2 | c.2531C>G p.A844G | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV100460708; called by muse, mutect2
- FBXL6 | c.1524C>G p.C508W | Missense Mutation (SNP) | VAF 124/223 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554852562; called by muse, mutect2, varscan2
- HHLA2 | c.598A>G p.N200D | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.231); catalogued as rs755382495; called by muse, mutect2
- HSPA4 | c.2342C>G p.P781R | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs775753031; called by muse, mutect2
- KCNQ4 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.334); catalogued as CM135001; called by muse, mutect2
- MUC4 | c.7241C>T p.A2414V | Missense Mutation (SNP) | VAF 26/854 reads (3%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.494); catalogued as rs879030787; called by muse, mutect2
- NUP107 | c.729+1G>A p.X243_splice | Splice Site (SNP) | VAF 12/97 reads (12%) | catalogued as COSV57492598; called by muse, mutect2, varscan2
- OR4N2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 35/412 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100270120, COSV60055300; called by muse, mutect2
- PALB2 | c.1238del p.T413Nfs*11 | Frame Shift Del (DEL) | VAF 59/247 reads (24%) | catalogued as COSV99849127; called by mutect2, pindel, varscan2
- SACS | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as rs752593308; called by muse, mutect2, varscan2
- SDK1 | c.2031C>A p.S677R | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs770971679; called by muse, mutect2, varscan2
- SP3 | c.1609C>T p.H537Y | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs1161421887; called by muse, mutect2
- SP5 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as rs923972235, COSV64622931; called by muse, mutect2, varscan2
- ACSL4 | c.1900G>A p.G634R (on ENST00000340800 / NM_022977.2; = p.G593R on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ARFGEF2 | c.4509G>T p.L1503F | Missense Mutation (SNP) | VAF 38/556 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- BMP2 | c.576G>C p.L192F | Missense Mutation (SNP) | VAF 23/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C2CD6 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CACNA1E | c.2334G>C p.W778C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- CCDC130 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CHIC2 | c.210A>T p.R70S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRM4 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2
- CILP | c.1594C>G p.Q532E | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- COG4 | c.1289A>G p.Y430C | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL14A1 | c.2941T>A p.S981T | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL14A1 | c.2942C>A p.S981Y | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- COL6A3 | c.1504del p.H502Ifs*8 | Frame Shift Del (DEL) | VAF 72/302 reads (24%) | called by mutect2, pindel, varscan2
- CSNK1A1 | c.628G>C p.V210L | Missense Mutation (SNP) | VAF 9/260 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); called by muse, mutect2
- DLG4 | c.1030G>C p.G344R (on ENST00000399506 / NM_001321075.3; = p.G387R on NM_001365.4) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH17 | c.10529A>T p.K3510M | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- GABRB3 | c.545-8C>A | Splice Region (SNP) | VAF 20/490 reads (4%) | called by muse, mutect2
- GJA3 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GON4L | c.5631+5G>A | Splice Region (SNP) | VAF 43/302 reads (14%) | called by muse, mutect2, varscan2
- HMCN2 | c.12395G>T p.R4132L | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- INSRR | c.2068T>C p.C690R | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF6 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 97/406 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- KRT32 | c.80G>T p.S27I | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- LTBP4 | c.1067A>T p.E356V (on ENST00000308370 / NM_001042544.1; = p.E319V on NM_003573.2) | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEGF8 | c.2903G>A p.W968* (on ENST00000251268 / NM_001271938.2; = p.W901* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 27/140 reads (19%) | called by muse, mutect2, varscan2
- NCK1 | c.644A>C p.D215A | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- NEK11 | c.1778G>C p.R593T | Missense Mutation (SNP) | VAF 98/331 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP5 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- OR5J2 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- PWWP2A | c.581A>G p.K194R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- RABEPK | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RAPGEF3 | c.565C>T p.P189S (on ENST00000389212; = p.P147S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RHBDL1 | c.302A>T p.E101V (on ENST00000219551 / NM_001318733.2; = p.E36V on NM_001278720.2) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); called by muse, mutect2
- RYR2 | c.6344A>G p.D2115G | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SACS | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SBK3 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35F5 | c.641A>T p.K214M | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMARCA1 | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 13/283 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.145); called by muse, mutect2
- SYNRG | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 19/380 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- TLN2 | c.7165C>T p.Q2389* | Nonsense Mutation (SNP) | VAF 67/260 reads (26%) | called by muse, mutect2, varscan2
- TMLHE | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 53/322 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- VIRMA | c.4007A>T p.N1336I | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2
- ZNF469 | c.3995A>C p.N1332T (on ENST00000437464; = p.N1360T on NM_001367624.2) | Missense Mutation (SNP) | VAF 10/350 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2
- ACP4 | c.543C>A p.G181= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV54516800; called by muse, mutect2
- ACSL1 | c.240G>A p.E80= | Silent (SNP) | VAF 24/286 reads (8%) | called by muse, mutect2
- ARHGEF33 | c.2148G>A p.P716= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- C9orf131 | c.3060G>A p.E1020= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, varscan2
- CC2D2A | c.1698G>A p.E566= | Silent (SNP) | VAF 36/160 reads (23%) | called by muse, mutect2, varscan2
- CD207 | c.645C>G p.T215= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as rs533675173; called by muse, mutect2, varscan2
- CD33 | c.987C>G p.A329= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- CLCN1 | c.2631G>A p.G877= | Silent (SNP) | VAF 56/169 reads (33%) | called by muse, mutect2, varscan2
- COL27A1 | c.5130C>T p.N1710= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as rs1405798136, COSV61922673; called by muse, mutect2
- CXCL6 | c.51C>T p.S17= | Silent (SNP) | VAF 27/189 reads (14%) | catalogued as rs775906428; called by muse, mutect2, varscan2
- FMO1 | c.1096C>T p.L366= | Silent (SNP) | VAF 98/208 reads (47%) | catalogued as COSV61447072; called by muse, mutect2, varscan2
- GTF2H3 | c.447G>A p.K149= | Silent (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- LMTK2 | c.210G>A p.K70= | Silent (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- LSP1 | c.6G>A p.A2= | Silent (SNP) | VAF 45/165 reads (27%) | catalogued as rs199891763; called by muse, mutect2, varscan2
- PLCB4 | c.2202A>T p.I734= | Silent (SNP) | VAF 13/149 reads (9%) | called by muse, mutect2
- PTPRQ | c.3489T>C p.Y1163= (on ENST00000616559; = p.Y1121= on NM_001145026.2) | Silent (SNP) | VAF 6/117 reads (5%) | called by muse, mutect2
- SARDH | c.2217T>C p.I739= | Silent (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- SFRP2 | c.465C>G p.L155= | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- TBCD | c.207G>A p.E69= | Silent (SNP) | VAF 48/249 reads (19%) | called by muse, mutect2, varscan2
- TRIOBP | c.319C>A p.R107= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs376056274; called by muse, varscan2
- TSPEAR | c.798C>T p.N266= | Silent (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- AL662791.2 | n.107G>C | RNA (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- AP000769.5 | chr11:65498988 T>A | 5'Flank (SNP) | VAF 73/295 reads (25%) | called by muse, mutect2, varscan2
- COPRS | c.99+318C>A | Intron (SNP) | VAF 39/379 reads (10%) | called by muse, mutect2, varscan2
- DST-AS1 | n.139+7334C>G | Intron (SNP) | VAF 10/90 reads (11%) | called by muse, varscan2
- GRM1 | c.950+15del | Intron (DEL) | VAF 54/172 reads (31%) | catalogued as rs1311706536; called by mutect2, varscan2*
- KIR3DL1 | c.-22G>A | 5'UTR (SNP) | VAF 40/346 reads (12%) | catalogued as rs544227512, COSV100428980; called by muse, varscan2
- KRT14 | c.-10C>A | 5'UTR (SNP) | VAF 58/137 reads (42%) | called by muse, mutect2, varscan2
- LUC7L | c.61+347G>A | Intron (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- RGS11 | c.658-35C>A | Intron (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- SAMSN1 | c.465+1377C>G | Intron (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- SLC26A8 | c.-106del | 5'UTR (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- TMCO3 | c.*81_*85del | 3'UTR (DEL) | VAF 51/205 reads (25%) | called by mutect2, pindel, varscan2
